Gene-level copy-number profile of tumor specimen ALCH-B3XW-TTP1-A from ALCHEMIST case ALCH-B3XW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 67.2 years (24,551 days).
Specimen ALCH-B3XW-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b241e4f3-4060-42ae-ab82-a1d37f4abc2b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3XW-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/ed2735d6-a4b5-4c43-87a9-7e7a9c80967c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 53; copy number 1: 18,327; copy number 2: 32,541; copy number 3: 6,166; copy number 4: 1,198; copy number 5: 109; copy number 6: 1; copy number 7: 2; copy number 8: 1; copy number 9: 2.

Homozygous deletions (total copy number 0; autosomes only): 52 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:100,375,700–100,381,398, 1 gene: AC113385.3.
- chr11:77,868,722–77,869,195, 1 gene (within-gene range 0–2): AP002812.1.
- chr13:19,674,752–19,818,619, 3 genes (within-gene range 0–1): PSPC1, RN7SL166P, ST6GALNAC4P1.
- chr15:25,172,635–25,257,027, 44 genes (within-gene range 0–2): SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44, AC124303.1.
- chr22:18,715,815–18,719,341, 1 gene: PPP1R26P4.
- chr22:18,794,414–18,794,804, 1 gene (within-gene range 0–2): AC008132.2.
- chr22:30,356,635–30,378,658, 1 gene (within-gene range 0–2): CCDC157.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 115 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:189,631,389–189,897,276, 1 gene, copy number 7 (within-gene range 4–7): TP63.
- chr3:189,829,922–190,122,437, 3 genes, copy number 5–7 (within-gene range 4–7): MIR944, P3H2, MTAPP2.
- chr9:32,836,575–34,774,466, 94 genes, copy number 5 (broad region; genes not listed).
- chr12:76,259,836–76,559,809, 4 genes, copy number 5: LNCOG, RN7SKP172, BBS10, OSBPL8.
- chr21:44,107,373–44,210,114, 3 genes, copy number 6–9 (within-gene range 1–9): PWP2, GATD3A, LINC01678.
- chr22:18,733,914–18,757,906, 1 gene, copy number 8: FAM230E.
- chr22:18,873,543–18,894,407, 2 genes, copy number 5: FAM230F, AC008103.1.
- chr22:50,523,568–50,551,023, 7 genes, copy number 5: SCO2, U62317.1, TYMP, ODF3B, U62317.3, KLHDC7B-DT, KLHDC7B.

Autosomal genes at a single copy (total copy number 1): 17,459. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
